Somatic mutation profile of tumor specimen ALCH-B4NQ-TTP1-A (aliquot ALCH-B4NQ-TTP1-A-6-0-D-A81V-36) from ALCHEMIST case ALCH-B4NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 37.1 years (13,558 days).
Specimen ALCH-B4NQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02c3209b-38d2-426c-bf90-654fe9fd46c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4NQ-NB1-A (Blood Derived Normal), aliquot ALCH-B4NQ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fd47f49-172d-42d2-aa8c-0873a8d21a2a

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Intron 4, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 45/316 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 204/705 reads (29%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 90/235 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.749T>A p.F250Y | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV63674502; called by muse, mutect2
- ANO2 | c.671C>T p.A224V (on ENST00000356134 / NM_001278597.3; = p.A228V on NM_001278596.3) | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1004961555, COSV100502527, COSV59043398; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2
- CPS1 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1559102901, CM114344, COSV51825265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERLIN1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs943655200; called by muse, mutect2
- FLG | c.11902G>T p.G3968C | Missense Mutation (SNP) | VAF 248/1368 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV64237667; called by muse, mutect2, varscan2
- INPP5E | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as rs775094328; called by muse, mutect2
- ITGAM | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs563980365, COSV54944134; called by muse, mutect2, varscan2
- NGEF | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773863661; called by muse, mutect2, varscan2
- NUP107 | c.552G>A p.Q184= | Splice Region (SNP) | VAF 25/55 reads (45%) | catalogued as COSV57496517; called by muse, mutect2, varscan2
- OLFM2 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 23/582 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); catalogued as rs758216718, COSV53432659; called by muse, mutect2
- OTUD7A | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs564035759; called by muse, mutect2
- PHRF1 | c.2500G>A p.D834N (on ENST00000264555 / NM_001286581.2; = p.D833N on NM_020901.4) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs766638984; called by muse, mutect2
- PTBP2 | c.1103-2dup | Splice Region (INS) | VAF 47/349 reads (13%) | catalogued as rs746856604; called by mutect2, pindel, varscan2
- SLC22A6 | c.777dup p.A260Cfs*11 | Frame Shift Ins (INS) | VAF 21/164 reads (13%) | catalogued as rs749849908; called by mutect2, varscan2
- WSCD2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as rs774657315, COSV54588289; called by muse, mutect2
- ZMYM2 | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1272256897; called by muse, mutect2, varscan2
- C18orf54 | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CDH8 | c.1193T>A p.L398H | Missense Mutation (SNP) | VAF 25/527 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- CXorf66 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAT3 | c.11473C>A p.P3825T | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- FAXC | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.909); called by muse, varscan2
- GNB5 | c.373C>T p.Q125* (on ENST00000261837 / NM_016194.4; = p.Q83* on NM_006578.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2
- IVD | c.371C>T p.A124V (on ENST00000651168; = p.A121V on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- LRRC4B | c.32del p.P11Rfs*33 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); called by muse, mutect2
- TMEM132D | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 103/444 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF18 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- WEE2 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB20 | c.374_380dup p.F128Qfs*31 (on ENST00000474710 / NM_001164342.2; = p.F55Qfs*31 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 62/224 reads (28%) | called by mutect2, varscan2
- ZNF724 | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- C11orf94 | c.261C>T p.P87= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1439455995, COSV53797269; called by muse, mutect2, varscan2
- EXOC5 | c.1746C>T p.Y582= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as rs767330860, COSV100566908, COSV61770445; called by muse, mutect2, varscan2
- GRM7 | c.1389T>A p.T463= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- KCNJ5 | c.1134G>A p.Q378= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- OR2L5 | c.87C>T p.L29= | Silent (SNP) | VAF 52/315 reads (17%) | catalogued as rs775826927; called by muse, mutect2, varscan2
- PCDH15 | c.1155A>T p.I385= | Silent (SNP) | VAF 100/425 reads (24%) | called by muse, mutect2, varscan2
- SRMS | c.612C>T p.I204= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- BAGE2 | n.123C>T | RNA (SNP) | VAF 28/401 reads (7%) | catalogued as rs1433172128; called by muse, mutect2
- CPSF1 | c.938-34G>A | Intron (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- JAK3 | c.3207+29C>T | Intron (SNP) | VAF 13/289 reads (4%) | called by muse, mutect2
- LIPM | c.148-2304G>A | Intron (SNP) | VAF 51/226 reads (23%) | catalogued as rs1356224947; called by muse, mutect2, varscan2
- PLD1 | c.-32+17701C>T | Intron (SNP) | VAF 90/300 reads (30%) | catalogued as rs1338284517; called by muse, mutect2, varscan2
